Somatic mutation profile of tumor specimen ALCH-B4F0-TTP1-A (aliquot ALCH-B4F0-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4F0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 79.9 years (29,187 days).
Specimen ALCH-B4F0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3465ebd3-33f5-446d-8f54-a9acfa6bf8bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4F0-NB1-A (Blood Derived Normal), aliquot ALCH-B4F0-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9d70528-ceb3-407c-8868-47167c968fa6

The open-access MAF lists 124 somatic variants for this specimen: 80 protein-altering or splice-affecting, 29 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 29, Nonsense Mutation 9, Intron 8, Splice Region 4, Splice Site 3, 5'UTR 3, RNA 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.1678G>T p.E560* | Nonsense Mutation (SNP) | VAF 14/299 reads (5%) | catalogued as COSV62326052; called by muse, mutect2
- ARHGEF3 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 24/532 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV58192016; called by muse, mutect2
- ARID2 | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57599678, COSV57606673, COSV57614708; called by muse, mutect2
- ARL14EPL | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 23/334 reads (7%) | catalogued as rs981988957, COSV59948454, COSV59948566; called by muse, mutect2
- C12orf57 | c.52+3G>A | Splice Region (SNP) | VAF 22/544 reads (4%) | catalogued as rs1449296027, COSV57546808; called by muse, mutect2
- C2CD3 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 20/452 reads (4%) | catalogued as COSV100486400; called by muse, mutect2
- CAMSAP2 | c.2434C>G p.L812V (on ENST00000236925 / NM_001297707.2; = p.L801V on NM_203459.3) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.231); catalogued as COSV52672422; called by muse, mutect2
- CHGB | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 29/503 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774481987; called by muse, mutect2
- CLECL1 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV59931817; called by muse, mutect2
- CTNNA3 | c.1875G>A p.M625I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV101051473, COSV65560547; called by muse, mutect2
- DNAH11 | c.6238C>G p.L2080V | Missense Mutation (SNP) | VAF 31/504 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100180093; called by muse, mutect2
- ENPP2 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV50011381; called by muse, mutect2
- F8 | c.5348G>C p.R1783T | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as CM055175; called by muse, mutect2
- GRIA2 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.831); catalogued as COSV52387390; called by muse, mutect2
- KCNJ10 | c.971T>C p.I324T | Missense Mutation (SNP) | VAF 41/972 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1170710028; called by muse, mutect2
- KCTD10 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs1246140028; called by muse, mutect2
- NFASC | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 22/674 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58357838; called by muse, mutect2
- PMS1 | c.2392G>A p.D798N | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59720228; called by muse, mutect2
- PWP1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 19/509 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV69832596; called by muse, mutect2
- PXDNL | c.3708C>A p.N1236K | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs761975554; called by muse, mutect2
- RYR1 | c.12541G>A p.E4181K | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as CM108383; called by muse, mutect2
- SLC36A2 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 23/651 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58865265; called by muse, mutect2
- SPTBN2 | c.6694G>A p.E2232K | Missense Mutation (SNP) | VAF 13/307 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1313081711; called by muse, mutect2
- TLL1 | c.508T>G p.F170V | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99285641, COSV99286566, COSV99287563; called by muse, mutect2
- TMPRSS5 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs978857618; called by muse, mutect2
- TXNDC15 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 32/982 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV64379216; called by muse, mutect2
- ZDHHC15 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs1363001791; called by muse, mutect2
- ZNF407 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.462); catalogued as COSV99996148; called by muse, mutect2
- ACSBG2 | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 50/1020 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ADCY1 | c.1398G>C p.L466F | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2
- ARHGAP10 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 13/284 reads (5%) | called by muse, mutect2
- C1orf53 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CDK13 | c.2980C>T p.Q994* | Nonsense Mutation (SNP) | VAF 39/713 reads (5%) | called by muse, mutect2
- CHST11 | c.499T>A p.Y167N | Missense Mutation (SNP) | VAF 29/746 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CTHRC1 | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.063); called by muse, mutect2
- DCC | c.1609G>T p.V537L | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- DCDC2C | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2
- DMRTA2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- DNAH9 | c.12242G>C p.G4081A | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DPYD | c.2227G>T p.G743* | Nonsense Mutation (SNP) | VAF 27/852 reads (3%) | called by muse, mutect2
- FBN2 | c.6721G>A p.E2241K | Missense Mutation (SNP) | VAF 20/531 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2
- FH | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 40/708 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLDC | c.2838+2T>A p.X946_splice | Splice Site (SNP) | VAF 42/526 reads (8%) | called by muse, mutect2
- GLI2 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HEPH | c.2127G>C p.M709I (on ENST00000343002; = p.M442I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- HLA-F | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 36/926 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- HNRNPH3 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHV3-38 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 30/659 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2
- IL12RB2 | c.666G>C p.V222= | Splice Region (SNP) | VAF 18/453 reads (4%) | called by muse, mutect2
- IL36B | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.647); called by muse, mutect2
- ITPR3 | c.4409G>A p.S1470N | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- LIX1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 33/754 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- LRP1 | c.7470G>T p.Q2490H | Missense Mutation (SNP) | VAF 33/454 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.28); called by muse, mutect2
- LRP1 | c.7471G>T p.D2491Y | Missense Mutation (SNP) | VAF 33/454 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRRC41 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- MED16 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- NDST3 | c.1442C>A p.T481N | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2
- NEFM | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 50/990 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- NIN | c.3089C>G p.S1030* | Nonsense Mutation (SNP) | VAF 13/270 reads (5%) | called by muse, mutect2
- NRDC | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 14/373 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- OLFML2B | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 13/376 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- OR2M7 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4F15 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2
- OR51I2 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAMR1 | c.252T>C p.G84= | Splice Region (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- PCBP1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 41/719 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); called by muse, mutect2
- PCDHB11 | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 20/472 reads (4%) | called by muse, mutect2
- PKP4 | c.3010-2A>T p.X1004_splice | Splice Site (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- PRKCA | c.1716G>A p.L572= | Splice Region (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- PYHIN1 | c.1286C>A p.T429K | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2
- RET | c.1000T>C p.W334R | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- RGPD4 | c.3933G>C p.Q1311H | Missense Mutation (SNP) | VAF 28/940 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.351); called by muse, mutect2
- SEC14L1 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 30/782 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2
- SLC12A1 | c.2151T>A p.F717L | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SMARCC2 | c.2255-1G>C p.X752_splice | Splice Site (SNP) | VAF 22/730 reads (3%) | called by muse, mutect2
- SPEN | c.2111G>C p.R704T | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TIAM1 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 15/437 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- TMIGD3 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2
- TRAFD1 | c.1403C>G p.S468* | Nonsense Mutation (SNP) | VAF 22/638 reads (3%) | called by muse, mutect2
- ZZEF1 | c.4159G>C p.E1387Q | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- ABT1 | c.54G>C p.G18= | Silent (SNP) | VAF 14/456 reads (3%) | called by muse, mutect2
- ADAP1 | c.600G>A p.L200= | Silent (SNP) | VAF 17/302 reads (6%) | called by muse, mutect2
- C11orf80 | c.1647C>A p.P549= | Silent (SNP) | VAF 17/256 reads (7%) | called by muse, mutect2
- CDS2 | c.417C>T p.F139= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- CSMD1 | c.3963C>T p.F1321= (on ENST00000520002; = p.F1320= on NM_033225.6) | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- CUX1 | c.2979G>A p.Q993= | Silent (SNP) | VAF 12/282 reads (4%) | catalogued as COSV99470846; called by muse, mutect2
- EPB41L1 | c.1437C>T p.I479= | Silent (SNP) | VAF 31/562 reads (6%) | called by muse, mutect2
- FZD7 | c.1086C>T p.F362= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as rs1448008298, COSV53809445; called by muse, mutect2
- GOLGB1 | c.6405G>A p.L2135= | Silent (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- GPRASP2 | c.1125C>T p.V375= | Silent (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- HMGXB3 | c.3612C>T p.F1204= (on ENST00000613459; = p.F958= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/928 reads (3%) | called by muse, mutect2
- KCNV1 | c.723G>T p.L241= | Silent (SNP) | VAF 31/368 reads (8%) | called by muse, mutect2
- KDM8 | c.624G>A p.L208= | Silent (SNP) | VAF 25/353 reads (7%) | catalogued as COSV99619190, COSV99619511; called by muse, mutect2
- LIG3 | c.1413G>A p.L471= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- MAGI2 | c.141G>A p.V47= | Silent (SNP) | VAF 20/454 reads (4%) | catalogued as COSV62684536; called by muse, mutect2
- MED12 | c.4767C>T p.L1589= | Silent (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- MS4A14 | c.1071T>C p.P357= | Silent (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- NPIPB2 | c.30G>A p.L10= | Silent (SNP) | VAF 14/1462 reads (1%) | called by muse, mutect2
- OR13H1 | c.732G>T p.L244= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- PGS1 | c.1644G>A p.V548= | Silent (SNP) | VAF 28/852 reads (3%) | called by muse, mutect2
- PLEC | c.12369G>T p.T4123= (on ENST00000322810 / NM_201380.4; = p.T4013= on NM_000445.5) | Silent (SNP) | VAF 21/394 reads (5%) | catalogued as COSV100515534; called by muse, mutect2
- PRKCB | c.1041G>T p.V347= | Silent (SNP) | VAF 20/288 reads (7%) | catalogued as COSV57773960; called by muse, mutect2
- PRRT2 | c.984C>T p.I328= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- PSG8 | c.525C>T p.D175= | Silent (SNP) | VAF 36/820 reads (4%) | catalogued as rs143424985, COSV60613068; called by muse, mutect2
- SAMD3 | c.873C>T p.F291= | Silent (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- TMEM270 | c.333G>T p.L111= | Silent (SNP) | VAF 15/299 reads (5%) | called by muse, mutect2
- TRIM29 | c.1464G>C p.S488= | Silent (SNP) | VAF 26/581 reads (4%) | called by muse, mutect2
- UBAP2 | c.1140G>A p.L380= | Silent (SNP) | VAF 27/537 reads (5%) | called by muse, mutect2
- ZC3H18 | c.1578G>A p.K526= | Silent (SNP) | VAF 13/370 reads (4%) | called by muse, mutect2
- AGPAT4 | c.348+4851C>T | Intron (SNP) | VAF 17/462 reads (4%) | called by muse, mutect2
- ANAPC15 | chr11:72107569 G>C | 3'Flank (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- C8orf87 | n.239A>T | RNA (SNP) | VAF 28/645 reads (4%) | called by muse, mutect2
- CHN2 | c.49+2992G>T | Intron (SNP) | VAF 27/515 reads (5%) | called by muse, mutect2
- CHN2 | c.49+2993G>T | Intron (SNP) | VAF 27/514 reads (5%) | called by muse, mutect2
- FKBP4 | c.106-874G>C | Intron (SNP) | VAF 19/511 reads (4%) | called by muse, mutect2
- FRMD8P1 | n.546C>T | RNA (SNP) | VAF 29/272 reads (11%) | called by muse, mutect2, varscan2
- GRIA4 | c.487+44681T>A | Intron (SNP) | VAF 11/67 reads (16%) | called by muse, varscan2
- JAKMIP1 | c.1708-643G>C | Intron (SNP) | VAF 28/710 reads (4%) | called by muse, mutect2
- MRPS5 | c.763+41A>T | Intron (SNP) | VAF 33/647 reads (5%) | called by muse, mutect2
- NDRG4 | c.-86C>G | 5'UTR (SNP) | VAF 24/283 reads (8%) | called by muse, mutect2
- NDUFA8 | c.-44G>A | 5'UTR (SNP) | VAF 9/145 reads (6%) | catalogued as COSV101055796; called by muse, mutect2
- ORC6 | c.-37G>A | 5'UTR (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2
- POU3F4 | c.*20G>C | 3'UTR (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 14/253 reads (6%) | catalogued as rs910081914; called by muse, mutect2
